Somatic mutation profile of tumor specimen MP2PRT-PAPCVI-TMP1-A (aliquot MP2PRT-PAPCVI-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPCVI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,541 days).
Specimen MP2PRT-PAPCVI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9a41868-7b93-4950-afaa-3a78d9620fbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPCVI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPCVI-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6913ee02-d493-42a9-b9c1-838f5dc4a05a

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 3'Flank 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 52/372 reads (14%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKS1A | c.952A>C p.T318P | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.091); catalogued as rs767137276; called by muse, mutect2, varscan2
- BPIFB3 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as rs753724962, COSV64957251; called by muse, mutect2, varscan2
- DLX4 | c.284-6C>T | Splice Region (SNP) | VAF 65/503 reads (13%) | catalogued as COSV99537678; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406869 CATTCACAGTGTT>G | Missense Mutation (DEL) | VAF 40/87 reads (46%) | called by pindel, varscan2*
- IGLV4-69 | chr22:22031467 CATTCACACAGTGACACAGG>TCA | Missense Mutation (DEL) | VAF 46/153 reads (30%) | called by pindel, varscan2*
- NXPE2 | c.1273G>C p.V425L | Missense Mutation (SNP) | VAF 104/268 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VWF | c.6068C>A p.T2023K | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ARX | c.579C>T p.G193= | Silent (SNP) | VAF 22/575 reads (4%) | called by muse, mutect2
- CLEC19A | c.285C>T p.L95= | Silent (SNP) | VAF 42/279 reads (15%) | catalogued as rs1340449619; called by muse, mutect2, varscan2
- OAS1 | c.624C>A p.L208= | Silent (SNP) | VAF 78/234 reads (33%) | called by mutect2, varscan2
- UGT2B4 | c.1443C>T p.H481= | Silent (SNP) | VAF 150/337 reads (45%) | catalogued as rs547579888, COSV59315571; called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins CCTCCA | 3'Flank (INS) | VAF 30/52 reads (58%) | called by pindel, varscan2
